Somatic mutation profile of tumor specimen MMRF_2017_2_BM_CD138pos (aliquot MMRF_2017_2_BM_CD138pos_T1_KHS5U_L11097) from MMRF case MMRF_2017, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.7 years (30,211 days).
Specimen MMRF_2017_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f7cfe71-8853-4d67-a540-4b6c8b4eea8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2017_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2017_1_PB_WBC_C3_KHS5U_L08821; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2883800d-7bf3-4d54-be98-4057e62cdc1b

The open-access MAF lists 120 somatic variants for this specimen: 47 protein-altering or splice-affecting, 16 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 37, Silent 16, Intron 12, Nonsense Mutation 2, 5'UTR 2, RNA 2, 3'Flank 2, 5'Flank 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>C p.R780T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 28/145 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACAN | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 50/227 reads (22%) | catalogued as COSV100718982, COSV61363169; called by muse, mutect2, varscan2
- ARHGAP18 | c.601T>A p.Y201N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63765450; called by muse, mutect2
- BSN | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | catalogued as COSV99609946; called by muse, mutect2, varscan2
- CDH18 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV99937554; called by muse, mutect2, varscan2
- CYLD | c.1950-1G>C p.X650_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as CD096639; called by muse, mutect2, varscan2
- E2F3 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV60899670; called by muse, mutect2, varscan2
- FAM104B | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); catalogued as rs1182217985; called by muse, mutect2, varscan2
- FHOD3 | c.3241A>C p.K1081Q (on ENST00000359247 / NM_001281739.3; = p.K1098Q on NM_025135.5) | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV57165299; called by muse, mutect2
- IGHV2-70D | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, varscan2
- INSYN2A | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs144141274, COSV99732163; called by muse, mutect2, varscan2
- KCNH2 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1402460942; called by muse, mutect2, varscan2
- LRRD1 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100588270; called by muse, mutect2
- MYH7B | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483327; called by muse, mutect2, varscan2
- NSUN2 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99243080; called by muse, mutect2, varscan2
- OR10C1 | c.662G>A p.R221H (on ENST00000622521; = p.R219H on NM_013941.3) | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs74711365, COSV65822383, COSV65822987; called by muse, mutect2
- PLEKHA6 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs377234378; called by muse, mutect2, varscan2
- SLC19A1 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as rs746905281; called by muse, mutect2, varscan2
- SPAG16 | c.1451T>A p.I484N | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216301084; called by muse, mutect2, varscan2
- STAC | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs145771131; called by muse, mutect2, varscan2
- TMCO5A | c.-8C>T | Splice Region (SNP) | VAF 29/218 reads (13%) | catalogued as rs781153645, COSV100148667; called by muse, mutect2, varscan2
- ULK1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1372824316, COSV58856766; called by muse, mutect2, varscan2
- VARS1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.719); catalogued as rs1388908895; called by mutect2, varscan2
- ADAMTS20 | c.3882T>A p.N1294K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BAG4 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- BNC1 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1E | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMKV | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- CEBPG | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHRNA1 | c.1418G>A p.G473D (on ENST00000261007 / NM_001039523.3; = p.G448D on NM_000079.4) | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- CTNNA2 | c.1147del p.A383Qfs*2 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- EIF2S1 | c.650A>T p.N217I | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.103); called by muse, mutect2
- FILIP1L | c.3019G>A p.V1007M (on ENST00000354552 / NM_182909.3; = p.V767M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- IGHV1-69D | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP2 | c.2391A>T p.K797N | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIS18A | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NMT2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- OR10C1 | c.329C>G p.A110G (on ENST00000622521; = p.A108G on NM_013941.3) | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2
- PCDHB7 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC26A7 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEK | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TJP1 | c.3488C>G p.P1163R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TULP2 | c.1455T>A p.H485Q | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WNK2 | c.2986C>G p.P996A | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF641 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- ABCC9 | c.2430C>T p.I810= | Silent (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- AMOTL2 | c.681T>G p.T227= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- CDK13 | c.4005C>T p.Y1335= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs117406419; called by muse, mutect2, varscan2
- CHD5 | c.3345C>G p.V1115= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- DELE1 | c.1266C>T p.A422= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs761073958; called by muse, mutect2, varscan2
- FAM160A2 | c.2631G>A p.A877= (on ENST00000449352 / NM_001098794.2; = p.A891= on NM_032127.4) | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs773167298, COSV56409746; called by muse, mutect2, varscan2
- FAT4 | c.6858T>C p.D2286= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as COSV58699280; called by muse, mutect2, varscan2
- GRIA4 | c.1341T>C p.C447= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- MAP3K11 | c.511C>T p.L171= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as COSV58418719; called by muse, mutect2, varscan2
- MYO7A | c.3615C>A p.S1205= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV68683677; called by muse, mutect2, varscan2
- OR1S2 | c.580T>C p.L194= | Silent (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- OTOF | c.4722G>C p.G1574= (on ENST00000272371 / NM_194248.3; = p.G807= on NM_004802.4) | Silent (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- REXO1 | c.2139C>G p.A713= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SPG7 | c.1986T>G p.P662= (on ENST00000268704; = p.P669= on NM_003119.4) | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- VLDLR | c.180C>T p.D60= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs151277117; called by muse, mutect2, varscan2
- WDR11 | c.717T>C p.A239= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- AC093791.1 | n.490G>A | RNA (SNP) | VAF 64/251 reads (25%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62072402 C>T | 3'Flank (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ALKBH4 | c.*85C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- ANXA2 | c.-11-111A>G | Intron (SNP) | VAF 14/125 reads (11%) | catalogued as rs1022653106; called by muse, mutect2, varscan2
- ATXN1 | c.*563G>A | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- BMPR1B | chr4:95155295 A>T | 3'Flank (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- C9orf85 | c.323+1697C>T | Intron (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- CBX6 | c.*3195C>T | 3'UTR (SNP) | VAF 6/117 reads (5%) | catalogued as rs1404938520; called by muse, mutect2
- CCDC3 | c.*1604T>C | 3'UTR (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- CEP192 | c.4258-29A>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CHP2 | c.*1258G>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- DARS1 | c.*573G>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as COSV51536807; called by muse, mutect2
- DNMT1 | c.1042-23C>T | Intron (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- DOCK5 | c.*2364G>C | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- DUSP22 | c.509-113G>A | Intron (SNP) | VAF 68/406 reads (17%) | catalogued as rs1322377107; called by muse, mutect2, varscan2
- EHMT1 | c.*34G>C | 3'UTR (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- ENDOV | chr17:80415000 C>T | 5'Flank (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- FAM20C | c.864-17411C>A | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, varscan2
- FARP1 | c.*1328C>T | 3'UTR (SNP) | VAF 21/153 reads (14%) | catalogued as rs976293921; called by muse, mutect2, varscan2
- FICD | c.*662del | 3'UTR (DEL) | VAF 6/52 reads (12%) | catalogued as rs889606437; called by mutect2, varscan2
- FKBP1C | c.*421del | 3'UTR (DEL) | VAF 55/218 reads (25%) | called by mutect2, pindel, varscan2
- FRG2C | c.*406T>C | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- FRMD4A | c.46-149538C>G | Intron (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- FRMD6 | c.*1261A>T | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- GPR150 | c.*509T>C | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- GTF2H1 | c.*1099G>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- IGSF22 | c.*564C>T | 3'UTR (SNP) | VAF 18/93 reads (19%) | catalogued as rs991292884; called by muse, mutect2, varscan2
- KCND1 | c.*1007T>C | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- LAMA1 | c.8207+53G>T | Intron (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- MTDH | c.*849T>C | 3'UTR (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- NUBPL | c.*106T>A | 3'UTR (SNP) | VAF 56/182 reads (31%) | called by muse, mutect2, varscan2
- NUBPL | c.*448T>C | 3'UTR (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- PCCA | c.1900-23739G>A | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- PCK2 | chr14:24094092 G>A | 5'Flank (SNP) | VAF 7/38 reads (18%) | catalogued as rs1264436010; called by muse, mutect2
- PEG10 | c.*939C>A | 3'UTR (SNP) | VAF 70/510 reads (14%) | called by muse, mutect2, varscan2
- PHOX2B | c.*1114G>A | 3'UTR (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- RASGRF1 | c.*1317G>A | 3'UTR (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- RBPJL | c.*135C>G | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- RGSL1 | c.*66T>A | 3'UTR (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- SLC26A9 | c.553-59G>A | Intron (SNP) | VAF 26/78 reads (33%) | catalogued as rs542014603, COSV61603608; called by muse, mutect2, varscan2
- SLC2A9 | c.-12T>C | 5'UTR (SNP) | VAF 18/92 reads (20%) | called by mutect2, varscan2
- SLC40A1 | c.*1008C>T | 3'UTR (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- SLC6A1 | c.*2011dup | 3'UTR (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- SLC9A7 | c.*25T>C | 3'UTR (SNP) | VAF 31/184 reads (17%) | catalogued as rs755341873; called by muse, mutect2, varscan2
- SMG7 | c.*153C>T | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- SOS1 | c.*2993del | 3'UTR (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- SOX11 | c.*4489C>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | catalogued as rs775910744, COSV100431130; called by muse, mutect2, varscan2
- SPATA31D5P | n.298A>T | RNA (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- SPATA6 | c.*1965C>A | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.585-21505C>A | Intron (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- STOML3 | c.*16G>A | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, varscan2
- TEKT1 | c.*1860A>G | 3'UTR (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- TMEM167B | c.*446G>A | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TMEM175 | c.-64C>T | 5'UTR (SNP) | VAF 15/41 reads (37%) | catalogued as rs758487337; called by muse, mutect2, varscan2
- TNC | c.*614G>A | 3'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- TNS1 | c.*2090C>G | 3'UTR (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- TNS1 | c.212-65T>C | Intron (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
